Somatic mutation profile of tumor specimen MP2PRT-PASRLT-TMP1-A (aliquot MP2PRT-PASRLT-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASRLT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,057 days).
Specimen MP2PRT-PASRLT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 80b50fd9-329c-4d6e-b8a1-696a559da2e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASRLT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASRLT-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52410e83-f4d1-4614-80d0-2d76c7d08c05

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Nonsense Mutation 4, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADH7 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 119/273 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs746547216; called by muse, mutect2, varscan2
- DENND3 | c.2701C>T p.P901S | Missense Mutation (SNP) | VAF 110/277 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs1319164778; called by muse, mutect2, varscan2
- HSDL2 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 101/248 reads (41%) | catalogued as COSV52717681; called by muse, mutect2, varscan2
- NEFL | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 244/556 reads (44%) | catalogued as COSV99647936; called by muse, mutect2, varscan2
- NRXN2 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 14/430 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs908791840; called by muse, mutect2
- PDE10A | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.154); catalogued as rs756499137, COSV63090599; called by muse, mutect2, varscan2
- SETBP1 | c.4498G>A p.A1500T | Missense Mutation (SNP) | VAF 224/596 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs200098271, COSV56337786; called by muse, mutect2, varscan2
- CLIP3 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 98/236 reads (42%) | called by muse, mutect2, varscan2
- CPNE1 | c.329T>A p.L110Q (on ENST00000352393; = p.L115Q on NM_003915.5) | Missense Mutation (SNP) | VAF 127/282 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTTNBP2 | c.3650A>G p.E1217G | Missense Mutation (SNP) | VAF 162/412 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV3-7 | chr14:106062141 TCACTGTGTCTCTCGCACAGTAA>CCCCTAAGACG | Missense Mutation (DEL) | VAF 97/157 reads (62%) | called by pindel, varscan2*
- KRT31 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2
- KRTAP5-11 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 157/431 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- MLXIPL | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 290/718 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PSMA4 | c.490A>G p.I164V | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SEMA6B | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 130/300 reads (43%) | called by muse, mutect2, varscan2
- SPINK2 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAJ48 | chr14:22490488 GTGTATC>TT | Missense Mutation (DEL) | VAF 184/227 reads (81%) | called by pindel, varscan2*
- CEACAM7 | c.615C>T p.S205= | Silent (SNP) | VAF 148/388 reads (38%) | catalogued as rs200263190, COSV50074735; called by muse, mutect2, varscan2
- MMP12 | c.264C>T p.H88= | Silent (SNP) | VAF 30/396 reads (8%) | catalogued as rs201720785, COSV58258994; called by muse, mutect2
- FRRS1L | c.-111G>A | 5'UTR (SNP) | VAF 16/438 reads (4%) | called by muse, mutect2
